Somatic mutation profile of tumor specimen ALCH-AELA-TTP1-A (aliquot ALCH-AELA-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AELA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 77.1 years (28,179 days).
Specimen ALCH-AELA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57746844-743f-4f39-b9d4-e2a25b144d46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELA-NB1-A (Blood Derived Normal), aliquot ALCH-AELA-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/349d7faa-4fe6-4b72-8ac7-8ee19095c22f

The open-access MAF lists 676 somatic variants for this specimen: 467 protein-altering or splice-affecting, 120 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 397, Silent 120, Intron 54, Nonsense Mutation 28, Frame Shift Del 16, 3'UTR 13, RNA 13, Splice Site 12, Splice Region 7, 5'UTR 6, In Frame Del 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP4S1 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 79/191 reads (41%) | catalogued as rs200440467, CM152094; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 91/184 reads (49%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as rs1555037629, COSV63292691; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 194/371 reads (52%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs146672001; called by muse, mutect2, varscan2
- AC126283.2 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.033); catalogued as COSV67098041, COSV67098536; called by muse, mutect2, varscan2
- ACACB | c.4174G>C p.V1392L | Missense Mutation (SNP) | VAF 39/323 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV58132690; called by muse, mutect2, varscan2
- ACOX3 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200416377; called by muse, mutect2, varscan2
- ADGRE3 | c.1949G>C p.R650T | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as rs781712544, COSV53734371; called by muse, mutect2, varscan2
- AICDA | c.427+5G>A | Splice Region (SNP) | VAF 73/382 reads (19%) | catalogued as rs781620760, COSV99984343; called by muse, mutect2, varscan2
- AIRE | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs775921321, CM156945, COSV52394739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP2S1 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99617391; called by muse, mutect2, varscan2
- ARHGAP15 | c.183G>T p.R61S | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV54484458, COSV54502638; called by muse, varscan2
- B4GALNT3 | c.2052G>T p.R684S | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV56751651; called by muse, mutect2, varscan2
- BLNK | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 162/529 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV56408909; called by muse, mutect2, varscan2
- BMP5 | c.968A>C p.N323T | Missense Mutation (SNP) | VAF 320/555 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV63700882; called by muse, mutect2, varscan2
- BPIFB4 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.32); catalogued as rs746328825; called by muse, mutect2, varscan2
- BRCA2 | c.8614G>T p.E2872* | Nonsense Mutation (SNP) | VAF 44/131 reads (34%) | catalogued as COSV66465493; called by muse, mutect2, varscan2
- BRINP3 | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 133/555 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66534364; called by muse, mutect2, varscan2
- C10orf120 | c.969G>C p.W323C | Missense Mutation (SNP) | VAF 73/400 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV61491967; called by muse, mutect2, varscan2
- C3 | c.4280G>A p.R1427K | Missense Mutation (SNP) | VAF 160/567 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV55582537; called by muse, mutect2, varscan2
- C5AR2 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57255861; called by muse, mutect2, varscan2
- CCDC150 | c.428A>C p.Q143P | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV55878947; called by muse, mutect2, varscan2
- CD6 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1257239446, COSV57836163; called by muse, mutect2, varscan2
- CHRD | c.841+2T>C p.X281_splice | Splice Site (SNP) | VAF 127/226 reads (56%) | catalogued as COSV99200413; called by muse, mutect2, varscan2
- COL5A1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 102/276 reads (37%) | catalogued as COSV65670138; called by muse, mutect2, varscan2
- CT47B1 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 121/208 reads (58%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs774833900, COSV100988925, COSV64891556; called by muse, mutect2, varscan2
- CTNNA2 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1277830599; called by muse, mutect2
- CYP11B2 | c.780G>T p.W260C | Missense Mutation (SNP) | VAF 179/808 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM104295, COSV59995749; called by muse, mutect2, varscan2
- DCAF16 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 77/242 reads (32%) | catalogued as rs1317700583; called by muse, mutect2, varscan2
- DCUN1D4 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as COSV58122339; called by muse, mutect2, varscan2
- DNAI2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 150/466 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs757238033, COSV56760101; called by muse, mutect2, varscan2
- DNASE1L3 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs202183427; called by muse, mutect2, varscan2
- DNHD1 | c.3887G>A p.R1296Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs960149892, COSV99601129; called by muse, mutect2, varscan2
- DSCAM | c.4310G>T p.R1437L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs534405933, COSV68024581, COSV68040303; called by muse, mutect2, varscan2
- DUOX1 | c.4499C>A p.P1500H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs1567023120; called by muse, mutect2, varscan2
- E2F2 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.237); catalogued as COSV62276193; called by muse, mutect2, varscan2
- ERAL1 | c.537-3C>G | Splice Region (SNP) | VAF 18/290 reads (6%) | catalogued as COSV99650516; called by muse, mutect2
- ERICH3 | c.4084G>C p.G1362R | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV100444963, COSV58604216; called by muse, mutect2, varscan2
- FAM186A | c.6952G>T p.G2318C | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348948063; called by muse, mutect2, varscan2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 32/110 reads (29%) | catalogued as rs755836480; called by mutect2, varscan2
- FOXC1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1489771788; called by muse, mutect2, varscan2
- FOXRED2 | c.1377G>T p.L459F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV53400939; called by muse, mutect2, varscan2
- FRY | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs1473433457, COSV66565533; called by muse, mutect2, varscan2
- FSCB | c.440del p.P147Lfs*2 | Frame Shift Del (DEL) | VAF 56/171 reads (33%) | catalogued as COSV61219806; called by mutect2, pindel, varscan2
- GALT | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as rs1469998825; called by muse, mutect2, varscan2
- GCN1 | c.7888C>G p.Q2630E | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100324540; called by muse, mutect2
- GIN1 | c.1131G>T p.W377C | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV67536120; called by muse, mutect2, varscan2
- GLMN | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV64860321; called by muse, mutect2, varscan2
- GNAS | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 128/474 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV58345055; called by muse, mutect2, varscan2
- GNGT1 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50353121; called by muse, varscan2
- GPR15 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs757658209; called by muse, mutect2, varscan2
- GPR150 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs757791987; called by muse, mutect2, varscan2
- GPR179 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766817595; called by muse, mutect2, varscan2
- GSDMA | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV56977181, COSV56977313; called by muse, mutect2, varscan2
- GYG1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 121/688 reads (18%) | catalogued as rs777291159, COSV99936855; called by muse, mutect2, varscan2
- HAUS3 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777534113; called by muse, mutect2, varscan2
- HELZ | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62379079; called by muse, mutect2, varscan2
- HIVEP3 | c.6848G>A p.G2283E | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99914260; called by muse, mutect2, varscan2
- HSPA12A | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs61741265, COSV65023751; called by mutect2, varscan2
- IGSF1 | c.3662T>C p.I1221T | Missense Mutation (SNP) | VAF 114/198 reads (58%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.979); catalogued as rs1064796725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS1 | c.5429G>A p.R1810Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1054258901; called by muse, mutect2, varscan2
- KHNYN | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs755915684; called by muse, mutect2, varscan2
- KLHL40 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV55132564; called by muse, mutect2, varscan2
- KRT39 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 96/353 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs775807739; called by muse, mutect2, varscan2
- KYAT3 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769147723; called by muse, varscan2
- LAMA5 | c.9532C>T p.Q3178* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV53367114, COSV53374403; called by muse, mutect2
- LAMB2 | c.4951C>T p.R1651W | Missense Mutation (SNP) | VAF 266/593 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs200165604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK2 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV100110049; called by muse, mutect2
- MAGOHB | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57899153; called by muse, mutect2, varscan2
- MAP2K4 | c.911del p.R304Hfs*14 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | catalogued as COSV100796461; called by mutect2, pindel, varscan2
- MAP4K1 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67713332; called by muse, mutect2, varscan2
- MAT2B | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 122/428 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.64); catalogued as COSV55201759; called by muse, mutect2, varscan2
- MED1 | c.4616C>G p.S1539C | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.753); catalogued as rs930653823, COSV56128955; called by muse, mutect2, varscan2
- MME | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as COSV100852487, COSV64709353, COSV64709653; called by muse, mutect2, varscan2
- MROH1 | c.3691G>A p.V1231I | Missense Mutation (SNP) | VAF 110/588 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs984316912; called by muse, mutect2, varscan2
- MSH2 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 93/456 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV51882827; called by muse, mutect2, varscan2
- MTRF1L | c.1115T>C p.L372S | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1443823384; called by muse, mutect2, varscan2
- MUC16 | c.9416G>T p.S3139I | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as rs760141333; called by muse, mutect2, varscan2
- MUC17 | c.5866C>T p.P1956S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs200456398, COSV60301224; called by muse, mutect2, varscan2
- NEB | c.3844C>T p.L1282F | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV51183137, COSV51418822; called by muse, mutect2, varscan2
- NEBL | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747650692; called by muse, mutect2, varscan2
- NLGN4X | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 164/623 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs141720696; called by muse, mutect2, varscan2
- OR10J1 | c.83T>G p.F28C | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71128233; called by muse, mutect2
- OR2AK2 | c.796C>A p.R266S | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV100823416; called by muse, mutect2, varscan2
- OR2G3 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1355656807; called by muse, mutect2, varscan2
- OR2G6 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.209); catalogued as COSV58574053; called by muse, mutect2, varscan2
- OR2L8 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV61728616; called by muse, mutect2, varscan2
- OR4A16 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.219); catalogued as rs745945050, COSV59043624, COSV59044725; called by muse, mutect2, varscan2
- OR4B1 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as rs1431092887; called by muse, mutect2, varscan2
- OR4N2 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100269455; called by muse, mutect2, varscan2
- OR7D2 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1381367972; called by muse, mutect2, varscan2
- OXSR1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.519); catalogued as COSV61258759; called by muse, mutect2, varscan2
- PANX2 | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as rs529017295, COSV99348503; called by muse, mutect2, varscan2
- PCDH10 | c.2917C>G p.L973V | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); catalogued as COSV52094183; called by muse, mutect2, varscan2
- PCDH11X | c.3985C>A p.R1329S | Missense Mutation (SNP) | VAF 176/361 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV104403083; called by muse, mutect2, varscan2
- PCDH15 | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV57387523; called by muse, mutect2
- PCDHA5 | c.2332G>C p.G778R | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); catalogued as COSV100972620; called by muse, mutect2, varscan2
- PCDHA6 | c.1256C>A p.S419* | Nonsense Mutation (SNP) | VAF 140/392 reads (36%) | catalogued as COSV101131218; called by muse, mutect2, varscan2
- PCDHB2 | c.1624del p.A542Rfs*2 | Frame Shift Del (DEL) | VAF 102/375 reads (27%) | catalogued as COSV99164373; called by mutect2, pindel, varscan2
- PCDHGA6 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 119/288 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs904228732; called by muse, mutect2, varscan2
- PDGFD | c.901del p.R301Afs*24 | Frame Shift Del (DEL) | VAF 142/621 reads (23%) | catalogued as COSV56383688; called by mutect2, pindel, varscan2
- PEX12 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 131/544 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99862249; called by muse, mutect2, varscan2
- PIP4P2 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV53439729; called by muse, mutect2, varscan2
- PKP2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs553098424, COSV50749979; called by muse, mutect2, varscan2
- PLEKHM1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 213/675 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as rs751248256, COSV69598729; called by muse, mutect2, varscan2
- PNPLA3 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 115/317 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs757077071; called by muse, mutect2, varscan2
- PROX1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV54776823; called by muse, mutect2, varscan2
- PTPN21 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs766154137; called by muse, mutect2, varscan2
- RBFOX1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763620262, COSV60944317; called by muse, mutect2, varscan2
- RPTOR | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV60803103; called by muse, mutect2, varscan2
- RTKN | c.895C>T p.R299C (on ENST00000272430 / NM_001015055.2; = p.R286C on NM_033046.2) | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs142913266; called by muse, mutect2, varscan2
- SAMD9L | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs757761934; called by muse, mutect2, varscan2
- SCLY | c.1157G>A p.R386Q (on ENST00000651534; = p.R378Q on NM_016510.7) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs150718596; called by muse, mutect2, varscan2
- SLC7A13 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99878744; called by muse, mutect2, varscan2
- SPOCD1 | c.1729-4A>G | Splice Region (SNP) | VAF 76/237 reads (32%) | catalogued as rs774570065; called by muse, mutect2, varscan2
- ST3GAL1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 20/112 reads (18%) | PolyPhen probably damaging (0.971); catalogued as rs368794586, COSV60614844; called by muse, mutect2
- SUPV3L1 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV62845049; called by muse, mutect2, varscan2
- TAB2 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 42/597 reads (7%) | catalogued as COSV53854676; called by muse, mutect2
- TCF21 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868283914; called by muse, mutect2, varscan2
- TCHHL1 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs145646463; called by muse, mutect2, varscan2
- TCP1 | c.1064G>C p.R355T | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV58458691; called by muse, mutect2, varscan2
- TELO2 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs368284673; called by muse, mutect2, varscan2
- TG | c.8140G>A p.D2714N | Missense Mutation (SNP) | VAF 122/527 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1055215249, COSV55086170, COSV99602216; called by muse, mutect2, varscan2
- TGM6 | c.2003T>G p.V668G | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99171770; called by muse, mutect2, varscan2
- THSD7B | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1334927927; called by muse, mutect2, varscan2
- THSD7B | c.4733C>A p.S1578Y (on ENST00000272643; = p.S1576Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1436488709; called by muse, varscan2
- TM6SF2 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV99363658; called by muse, mutect2, varscan2
- TNNT1 | c.388-1G>C p.X130_splice | Splice Site (SNP) | VAF 40/400 reads (10%) | catalogued as COSV99402653; called by muse, mutect2
- TNR | c.688T>A p.C230S | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99690996; called by muse, mutect2, varscan2
- TRPM1 | c.56del p.P19Lfs*71 | Frame Shift Del (DEL) | VAF 79/348 reads (23%) | catalogued as COSV56642275; called by pindel, varscan2
- TSR2 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as COSV64308223; called by muse, mutect2, varscan2
- TTN | c.29504G>T p.R9835L (on ENST00000591111; = p.R8908L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/279 reads (30%) | PolyPhen possibly damaging (0.806); catalogued as rs375796685, COSV60318121; called by muse, mutect2, varscan2
- TTN | c.26326G>C p.V8776L (on ENST00000591111; = p.V7849L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/129 reads (33%) | PolyPhen benign (0.081); catalogued as COSV60045095; called by muse, mutect2, varscan2
- TTN | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 111/316 reads (35%) | PolyPhen probably damaging (0.999); catalogued as rs939333996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2J1 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 161/604 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs766552187; called by muse, mutect2, varscan2
- UMOD | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 114/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768490922; called by muse, mutect2, varscan2
- VCAN | c.3938C>A p.P1313Q | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV54109917; called by muse, mutect2, varscan2
- VHLL | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.482); catalogued as COSV100372614; called by muse, mutect2, varscan2
- WDR59 | c.2426G>C p.R809T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV100049143; called by muse, mutect2
- WNT2B | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as rs1454872972, COSV56672238; called by muse, mutect2, varscan2
- ZFHX4 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51479885, COSV99265906; called by muse, mutect2, varscan2
- ZNF114 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV59945729; called by muse, mutect2, varscan2
- ZNF536 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV62825304; called by muse, mutect2, varscan2
- ZNF716 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.755); catalogued as COSV70780819; called by muse, mutect2, varscan2
- ZNF804B | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1444643952; called by muse, mutect2, varscan2
- ZP1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs1229782097, COSV53926883, COSV99613002; called by muse, mutect2, varscan2
- ABCA4 | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 177/600 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- AC099489.1 | c.4697G>C p.R1566P | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ACACA | c.3945T>G p.D1315E | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- ACAD8 | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 133/570 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ACAP2 | c.1701G>C p.Q567H | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2
- ACTC1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ADAMTS3 | c.1599+2T>A p.X533_splice | Splice Site (SNP) | VAF 21/104 reads (20%) | called by muse, varscan2
- ADGRG2 | c.362_372del p.F121* (on ENST00000379869 / NM_001079858.3; = p.F118* on NM_005756.4) | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- ADRM1 | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- AGAP5 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 251/1346 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AGBL2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.11552G>T p.G3851V | Missense Mutation (SNP) | VAF 142/527 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.11486C>G p.S3829C | Missense Mutation (SNP) | VAF 119/416 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ALDH2 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- ALK | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 239/868 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ALPK2 | c.277_289del p.F93Vfs*151 | Frame Shift Del (DEL) | VAF 66/204 reads (32%) | called by mutect2, pindel
- AMY2B | c.1438A>T p.I480F | Missense Mutation (SNP) | VAF 98/490 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ANKFN1 | c.3568C>G p.Q1190E (on ENST00000653862; = p.Q1043E on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ANKLE1 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKLE2 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANP32E | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ARHGAP11A | c.300T>C p.N100= | Splice Region (SNP) | VAF 53/254 reads (21%) | called by muse, mutect2, varscan2
- ARID1B | c.5038G>T p.D1680Y | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ASB4 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ASCC2 | c.572A>C p.Y191S | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ASXL2 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ATP1A4 | c.2865G>A p.M955I | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- B4GALNT3 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BBS12 | c.1979C>A p.P660Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- BIRC6 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BLM | c.3860A>G p.E1287G | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- BMX | c.291_297del p.S98Vfs*4 | Frame Shift Del (DEL) | VAF 48/95 reads (51%) | called by mutect2, pindel, varscan2
- BRPF3 | c.3279+1G>A p.X1093_splice | Splice Site (SNP) | VAF 64/145 reads (44%) | called by muse, mutect2, varscan2
- C12orf42 | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- C2CD3 | c.6656G>A p.G2219D | Missense Mutation (SNP) | VAF 184/657 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf37 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAP2 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 117/457 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CCDC168 | c.20267C>T p.S6756L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCDC168 | c.4593G>T p.M1531I | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCDC170 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 93/371 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CCL28 | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC20B | c.1441A>T p.R481W | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CDO1 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- CEP83 | c.1734G>C p.L578F | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- CEP89 | c.1132A>G p.K378E | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CFAP299 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- CFAP46 | c.2972T>A p.I991N | Missense Mutation (SNP) | VAF 94/164 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CFAP69 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD7 | c.6256G>T p.D2086Y | Missense Mutation (SNP) | VAF 212/535 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CHMP7 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2
- CIBAR2 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); called by muse, varscan2
- CILP2 | c.3181G>T p.V1061F | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CLCA2 | c.871A>T p.M291L | Missense Mutation (SNP) | VAF 38/503 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- CLCN1 | c.2846G>T p.G949V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CLCN6 | c.1052T>C p.F351S | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLEC5A | c.471_478del p.N158Lfs*11 | Frame Shift Del (DEL) | VAF 44/201 reads (22%) | called by mutect2, pindel, varscan2
- CMYA5 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNIH4 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CNTNAP5 | c.1199A>C p.K400T | Missense Mutation (SNP) | VAF 113/447 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A6 | c.3325G>C p.G1109R | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.2430G>A p.K810= | Splice Region (SNP) | VAF 103/253 reads (41%) | called by muse, mutect2, varscan2
- CPS1 | c.2011A>C p.T671P | Missense Mutation (SNP) | VAF 80/453 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK1A1L | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- CTAGE1 | c.588G>T p.L196F | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CTDP1 | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CTSF | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTNBP2 | c.2556C>A p.D852E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.092); called by muse, mutect2
- DDX18 | c.1945G>C p.V649L | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.086); called by muse, varscan2
- DDX39A | c.733-1G>T p.X245_splice | Splice Site (SNP) | VAF 52/145 reads (36%) | called by muse, mutect2, varscan2
- DGKK | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DLD | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DMD | c.5222T>A p.L1741* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- DNAH9 | c.7816C>A p.L2606I | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNMT3B | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DNTTIP1 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK10 | c.3245T>C p.M1082T | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DPP10 | c.2267A>G p.D756G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- E2F4 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDNRA | c.94A>G p.N32D | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- EIF2B5 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 144/825 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- EIF4H | c.280T>G p.S94A | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ELF5 | c.409G>C p.E137Q (on ENST00000312319 / NM_198381.2; = p.E127Q on NM_001422.4) | Missense Mutation (SNP) | VAF 82/569 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- EMID1 | c.1082C>G p.P361R | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EOGT | c.312-1G>C p.X104_splice | Splice Site (SNP) | VAF 52/129 reads (40%) | called by muse, mutect2, varscan2
- EPB41L4A | c.1382C>A p.A461D | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPHA5 | c.2894G>C p.G965A | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ERBIN | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERFE | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ERN1 | c.2870dup p.Q958Pfs*45 | Frame Shift Ins (INS) | VAF 30/137 reads (22%) | called by mutect2, pindel, varscan2
- EVPL | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- FAM118A | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FAM186A | c.4063C>G p.Q1355E | Missense Mutation (SNP) | VAF 128/534 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, varscan2
- FER1L6 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FMNL1 | c.2492C>G p.S831C | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FMO2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.16222T>C p.S5408P | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, varscan2
- GGA1 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- GGACT | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, varscan2
- GIN1 | c.1130G>T p.W377L | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GLI1 | c.3062G>T p.G1021V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPIHBP1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 180/783 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- GPR142 | c.358+3G>A | Splice Region (SNP) | VAF 60/241 reads (25%) | called by muse, mutect2, varscan2
- GPR174 | c.955T>C p.F319L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR22 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GPRIN1 | c.741C>G p.D247E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- GRAMD1C | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- GVQW3 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2
- H2BC5 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 198/355 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HCFC2 | c.1365A>C p.K455N | Missense Mutation (SNP) | VAF 13/269 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.179); called by muse, mutect2
- HDAC11 | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC2 | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 50/231 reads (22%) | called by muse, mutect2, varscan2
- HNRNPF | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HPS3 | c.2571_2573del p.E857del | In Frame Del (DEL) | VAF 18/164 reads (11%) | called by pindel, varscan2
- HSF4 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HYOU1 | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IGKV2D-30 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- IL27RA | c.648G>T p.L216F | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ILDR2 | c.1273G>C p.V425L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSRR | c.2341A>T p.T781S | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, mutect2
- IRGQ | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ISLR2 | c.1076A>T p.N359I | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA4 | c.1440_1444del p.R481Efs*3 | Frame Shift Del (DEL) | VAF 47/244 reads (19%) | called by mutect2, pindel, varscan2
- ITGAD | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ITIH3 | c.735T>A p.N245K | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- JAG1 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 178/650 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, varscan2
- JAK3 | c.2457G>C p.E819D | Missense Mutation (SNP) | VAF 90/681 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- JAKMIP1 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- JPH2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KCND3 | c.1229A>C p.Y410S | Missense Mutation (SNP) | VAF 16/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ13 | c.603T>G p.S201R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK6 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KCNS2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF23 | c.2016G>T p.E672D | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, varscan2
- KIT | c.2602A>C p.S868R | Missense Mutation (SNP) | VAF 191/639 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KMT2C | c.9239C>G p.S3080* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- KNTC1 | c.6623T>G p.L2208* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
- KRT39 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- KRT81 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- KRT83 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 135/530 reads (25%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- LAIR1 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LDLRAD3 | c.194-9_206del p.X65_splice | Splice Site (DEL) | VAF 72/394 reads (18%) | called by mutect2, pindel
- LGALSL | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- LIMCH1 | c.1114A>T p.K372* | Nonsense Mutation (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- LINC00634 | c.148A>T p.R50W | Missense Mutation (SNP) | VAF 12/264 reads (5%) | PolyPhen benign (0.412); called by muse, mutect2
- LMF2 | c.1819A>T p.K607* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- LPO | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP6 | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRC43 | c.23A>C p.E8A | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4B | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRFIP1 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP3 | c.3107-7C>G | Splice Region (SNP) | VAF 45/170 reads (26%) | called by muse, mutect2, varscan2
- LY6G5C | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated, low confidence (0.41); called by muse, mutect2
- LYST | c.4003C>G p.Q1335E | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MAP1A | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP2 | c.4810G>A p.G1604S | Missense Mutation (SNP) | VAF 134/393 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPK11 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MARCHF4 | c.615C>A p.C205* | Nonsense Mutation (SNP) | VAF 58/126 reads (46%) | called by muse, varscan2
- MARS2 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAST4 | c.5846_5864del p.D1949Afs*16 (on ENST00000403625 / NM_001164664.2; = p.D1760Afs*16 on NM_015183.3) | Frame Shift Del (DEL) | VAF 44/129 reads (34%) | called by mutect2, pindel, varscan2
- MATR3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MED12 | c.5074G>C p.E1692Q | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MEIOC | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MELTF | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- METTL8 | c.279C>G p.Y93* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- MKI67 | c.3639_3645delinsCA p.P1214Rfs*13 | Frame Shift Del (DEL) | VAF 88/277 reads (32%) | called by pindel, varscan2*
- MKI67 | c.3223_3238del p.I1075Pfs*3 | Frame Shift Del (DEL) | VAF 211/588 reads (36%) | called by mutect2, pindel, varscan2
- MMP16 | c.622C>G p.H208D | Missense Mutation (SNP) | VAF 127/277 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MOSPD2 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 45/88 reads (51%) | called by muse, varscan2
- MS4A15 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSR1 | c.207_214del p.I70Sfs*14 | Frame Shift Del (DEL) | VAF 50/264 reads (19%) | called by pindel, varscan2
- MYO10 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MYO15B | c.9326C>T p.P3109L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.3906G>C p.E1302D | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NAA10 | c.483_485del p.H161_L162delinsQ | In Frame Del (DEL) | VAF 53/89 reads (60%) | called by mutect2, pindel, varscan2
- NAGS | c.1556_1566del p.K519Rfs*9 | Frame Shift Del (DEL) | VAF 147/548 reads (27%) | called by mutect2, pindel, varscan2
- NARF | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NEFM | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFE2L2 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- NFKBIE | c.1042G>T p.E348* (on ENST00000275015; = p.E209* on NM_004556.3) | Nonsense Mutation (SNP) | VAF 66/234 reads (28%) | called by muse, mutect2, varscan2
- NKX6-2 | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NLE1 | c.19-7_30del p.X7_splice | Splice Site (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- NLRP12 | c.2606C>T p.T869I | Missense Mutation (SNP) | VAF 207/491 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- NLRX1 | c.1256T>C p.L419S | Missense Mutation (SNP) | VAF 137/470 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOMO2 | c.1782T>G p.C594W | Missense Mutation (SNP) | VAF 106/502 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NONO | c.440G>C p.S147T | Missense Mutation (SNP) | VAF 130/207 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NUFIP1 | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, varscan2
- NUP153 | c.1952G>C p.G651A | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NUP155 | c.3765T>G p.Y1255* (on ENST00000231498 / NM_153485.3; = p.Y1196* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 73/397 reads (18%) | called by muse, mutect2, varscan2
- NUP210L | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- NUSAP1 | c.1313T>C p.L438S | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NXPE2 | c.637A>T p.R213W | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR12D3 | c.526T>C p.F176L | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OR13J1 | c.170_171insCCGT p.P58Rfs*65 | Frame Shift Ins (INS) | VAF 25/118 reads (21%) | called by mutect2, pindel*, varscan2*
- OR2T10 | c.788G>C p.S263T | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR4A5 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5AR1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 128/428 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OR6N1 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6Q1 | c.146del p.L49* | Frame Shift Del (DEL) | VAF 78/333 reads (23%) | called by mutect2, pindel, varscan2
- OR6X1 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ORC1 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- OSBPL7 | c.1894T>A p.F632I | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- PACS2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PANK3 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.144); called by muse, mutect2
- PCDHGB5 | c.2370_2378del p.S791_S793del | In Frame Del (DEL) | VAF 70/229 reads (31%) | called by mutect2, pindel, varscan2
- PDE6C | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 138/512 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PDE6C | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 122/422 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDZD2 | c.7480G>C p.D2494H | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZD7 | c.2756T>C p.L919P | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- PEX12 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PHF20L1 | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PIK3C2A | c.1846G>C p.D616H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PLAU | c.368+2_368+10del p.X123_splice | Splice Site (DEL) | VAF 28/109 reads (26%) | called by mutect2, pindel, varscan2
- POLB | c.153C>G p.H51Q | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PON3 | c.202-5_214del p.X68_splice | Splice Site (DEL) | VAF 33/235 reads (14%) | called by mutect2, pindel
- PPP1R9B | c.1495C>G p.L499V | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PRAMEF11 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PRAMEF19 | c.777C>G p.F259L | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRR36 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 110/390 reads (28%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- PRX | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PTPRF | c.4354C>G p.L1452V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PWWP3A | c.1250G>T p.W417L (on ENST00000627377; = p.W416L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- QRICH2 | c.3964-1G>A p.X1322_splice | Splice Site (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- RANBP2 | c.5641G>C p.E1881Q | Missense Mutation (SNP) | VAF 102/367 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- RASAL3 | c.2128C>G p.Q710E | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- RBL2 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBM46 | c.1271T>A p.V424E | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RFC1 | c.2318A>G p.Q773R (on ENST00000381897 / NM_001363496.2; = p.Q772R on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RMND1 | c.711G>T p.W237C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROPN1 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RUNDC3B | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RYR1 | c.9503C>G p.T3168R | Missense Mutation (SNP) | VAF 160/512 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- RYR2 | c.11950T>A p.S3984T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RYR3 | c.5528T>A p.F1843Y | Missense Mutation (SNP) | VAF 107/362 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SALL3 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL3 | c.2939G>C p.G980A | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN9A | c.3337G>C p.E1113Q (on ENST00000303354; = p.E1102Q on NM_002977.3) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- SCRIB | c.1462A>T p.I488F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SEC23IP | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEL1L | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SEL1L2 | c.364A>G p.K122E | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, varscan2
- SERINC3 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINI1 | c.197G>C p.G66A | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD2 | c.5340G>T p.W1780C | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SFTPD | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- SHKBP1 | c.761A>T p.E254V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SHOC1 | c.2113C>G p.Q705E | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- SIPA1 | c.3029G>C p.R1010T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SIPA1L2 | c.5026A>G p.K1676E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2
- SLC25A28 | c.939G>C p.R313S | Missense Mutation (SNP) | VAF 348/571 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLC27A3 | c.1528C>G p.L510V (on ENST00000271857; = p.L382V on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC45A1 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A8 | c.2168C>T p.T723I | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A2 | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 116/399 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCC2 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SMC6 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SOX5 | c.1318C>G p.P440A | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SPATA31E1 | c.3419C>A p.A1140D | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SPEM2 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SRP54 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- SSC5D | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 60/152 reads (39%) | called by muse, mutect2, varscan2
- SSH2 | c.3129A>T p.K1043N | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.831T>G p.H277Q | Missense Mutation (SNP) | VAF 47/166 reads (28%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAB2 | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- STRA6 | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STXBP2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- STXBP5 | c.1074T>A p.D358E | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUGP2 | c.1241C>A p.T414N | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.34); called by mutect2, varscan2
- SVEP1 | c.7787G>A p.C2596Y | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.10640C>A p.A3547D (on ENST00000367255 / NM_182961.4; = p.A3554D on NM_033071.3) | Missense Mutation (SNP) | VAF 227/344 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TANC1 | c.3989C>T p.P1330L | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TATDN2 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D28 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TBX19 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 185/634 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCAP | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TEAD3 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- TENT4A | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 119/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TEX13C | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 118/200 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TEX14 | c.3002G>C p.R1001T (on ENST00000240361 / NM_001201457.2; = p.R995T on NM_031272.5) | Missense Mutation (SNP) | VAF 119/377 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- THBS3 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- THRAP3 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TINAG | c.757G>C p.A253P | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- TLK1 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132C | c.1207T>C p.W403R | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TNNT1 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 42/406 reads (10%) | called by muse, mutect2
- TRBV7-1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TREM1 | c.50-2A>C p.X17_splice | Splice Site (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2
- TRERF1 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- TRIM32 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 337/513 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TRIML2 | c.61A>T p.T21S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- TRPM1 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- TSTD2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TTC14 | c.1532A>G p.E511G | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TTN | c.62653G>C p.E20885Q (on ENST00000591111; = p.E13461Q on NM_003319.4) | Missense Mutation (SNP) | VAF 119/347 reads (34%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBE3C | c.2320_2340del p.R774_L780del | In Frame Del (DEL) | VAF 58/287 reads (20%) | called by mutect2, pindel, varscan2
- UBE4A | c.1324C>G p.L442V (on ENST00000252108 / NM_001204077.2; = p.L449V on NM_004788.4) | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT2A1 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 103/382 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC93A | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- USF3 | c.2636C>G p.S879C | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- VCL | c.1773G>T p.M591I | Missense Mutation (SNP) | VAF 96/670 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- WDFY3 | c.2119A>G p.K707E | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR38 | c.602C>A p.S201* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- XRN1 | c.4538C>G p.P1513R | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- YTHDC2 | c.3518C>G p.S1173C | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- YY1AP1 | c.1795G>T p.V599F (on ENST00000295566 / NM_139118.2; = p.V542F on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ZBTB11 | c.1895C>G p.S632C | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ZBTB16 | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 144/494 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZBTB34 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 149/363 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB37 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZFHX4 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZMPSTE24 | c.150T>A p.H50Q | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF146 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 62/199 reads (31%) | called by muse, mutect2, varscan2
- ZNF225 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF385B | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF585B | c.2211G>C p.Q737H | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ZNF644 | c.3443A>G p.N1148S | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF696 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF732 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF770 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ZNF787 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ZNF99 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADM | c.162A>G p.K54= | Silent (SNP) | VAF 97/302 reads (32%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.703T>C p.L235= | Silent (SNP) | VAF 73/194 reads (38%) | catalogued as rs1220536828; called by muse, mutect2, varscan2
- ANKLE2 | c.810G>A p.V270= | Silent (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- ANKRD52 | c.2013G>A p.L671= | Silent (SNP) | VAF 72/282 reads (26%) | called by muse, mutect2, varscan2
- APLP1 | c.1146C>T p.A382= | Silent (SNP) | VAF 37/167 reads (22%) | catalogued as rs745752245; called by muse, mutect2, varscan2
- ATP13A1 | c.3600G>A p.L1200= | Silent (SNP) | VAF 43/178 reads (24%) | called by muse, mutect2, varscan2
- ATP2B4 | c.2704C>A p.R902= | Silent (SNP) | VAF 82/372 reads (22%) | catalogued as COSV58174463; called by muse, mutect2, varscan2
- AXIN1 | c.1566G>A p.A522= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs569298843, COSV51994749; called by muse, mutect2
- BIN1 | c.459C>T p.A153= | Silent (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
- CACNA1S | c.5364C>T p.I1788= | Silent (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- CDH26 | c.1149G>C p.V383= | Silent (SNP) | VAF 35/838 reads (4%) | called by muse, mutect2
- CDKN2A | c.204G>T p.A68= | Silent (SNP) | VAF 94/188 reads (50%) | catalogued as COSV58690330, COSV58720624; called by muse, mutect2, varscan2
- CEP152 | c.3774C>T p.C1258= (on ENST00000380950 / NM_001194998.2; = p.C1202= on NM_014985.4) | Silent (SNP) | VAF 167/612 reads (27%) | catalogued as COSV57860257; called by muse, mutect2, varscan2
- CERK | c.1221C>T p.L407= | Silent (SNP) | VAF 67/224 reads (30%) | called by muse, mutect2, varscan2
- CHL1 | c.765G>T p.G255= (on ENST00000397491 / NM_001253387.1; = p.G271= on NM_006614.4) | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as COSV99851864; called by muse, mutect2, varscan2
- CKM | c.243C>T p.S81= | Silent (SNP) | VAF 66/216 reads (31%) | called by muse, mutect2, varscan2
- COL8A2 | c.6G>A p.L2= | Silent (SNP) | VAF 59/244 reads (24%) | called by muse, mutect2, varscan2
- CSKMT | c.627G>C p.L209= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- CTSH | c.570C>T p.F190= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs754501669; called by muse, mutect2
- CUX2 | c.3963G>A p.L1321= | Silent (SNP) | VAF 49/318 reads (15%) | called by muse, mutect2, varscan2
- CX3CL1 | c.105G>A p.T35= | Silent (SNP) | VAF 14/254 reads (6%) | catalogued as rs959710757; called by muse, mutect2
- CYP46A1 | c.819C>T p.A273= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1320071109; called by muse, mutect2, varscan2
- CYP4F3 | c.1452C>A p.L484= | Silent (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- DAB1 | c.645G>A p.T215= | Silent (SNP) | VAF 72/331 reads (22%) | catalogued as rs267598673; called by muse, mutect2, varscan2
- DCLRE1B | c.1314A>C p.T438= | Silent (SNP) | VAF 64/482 reads (13%) | called by muse, mutect2, varscan2
- DCUN1D3 | c.762C>T p.G254= | Silent (SNP) | VAF 69/257 reads (27%) | called by muse, mutect2, varscan2
- DNASE2B | c.1047A>G p.A349= | Silent (SNP) | VAF 62/134 reads (46%) | catalogued as rs776351674; called by muse, mutect2, varscan2
- DNHD1 | c.7764C>T p.H2588= | Silent (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- DOCK4 | c.2463T>C p.Y821= | Silent (SNP) | VAF 79/357 reads (22%) | called by muse, mutect2, varscan2
- EEF1G | c.1023C>T p.L341= | Silent (SNP) | VAF 98/334 reads (29%) | called by muse, mutect2, varscan2
- EHMT1 | c.63G>A p.V21= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- EVX1 | c.477C>T p.T159= | Silent (SNP) | VAF 57/118 reads (48%) | catalogued as rs759035279; called by muse, mutect2, varscan2
- F5 | c.3570C>T p.L1190= | Silent (SNP) | VAF 82/318 reads (26%) | called by muse, mutect2, varscan2
- FAM135B | c.3042G>C p.L1014= | Silent (SNP) | VAF 37/167 reads (22%) | called by muse, mutect2, varscan2
- FAM200A | c.1692T>C p.L564= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- FAM214B | c.429C>A p.P143= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs757819380; called by mutect2, varscan2
- FAT3 | c.10023C>T p.F3341= | Silent (SNP) | VAF 98/338 reads (29%) | called by muse, mutect2, varscan2
- FBN3 | c.1419G>C p.R473= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- FKBP10 | c.714C>T p.G238= | Silent (SNP) | VAF 38/513 reads (7%) | catalogued as rs1319609730, COSV58637938; called by muse, mutect2
- FOXN2 | c.306G>A p.Q102= | Silent (SNP) | VAF 116/240 reads (48%) | catalogued as rs1047987448, COSV100489345; called by muse, varscan2
- FSD2 | c.549T>C p.C183= | Silent (SNP) | VAF 116/261 reads (44%) | called by muse, mutect2, varscan2
- GABRA4 | c.1389T>C p.Y463= | Silent (SNP) | VAF 25/383 reads (7%) | catalogued as rs1391743852; called by muse, mutect2
- GARS1 | c.363A>C p.R121= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- GPR139 | c.891C>T p.A297= | Silent (SNP) | VAF 162/511 reads (32%) | catalogued as rs777959400; called by muse, mutect2, varscan2
- GRIN3B | c.1245C>G p.P415= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- HOXD11 | c.561G>A p.G187= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs1559113751; called by muse, mutect2, varscan2
- IQSEC3 | c.57G>A p.T19= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as rs1277843590; called by mutect2, varscan2
- IRF2BP2 | c.1743G>C p.V581= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV64014630; called by muse, mutect2
- KAT6B | c.399C>G p.L133= | Silent (SNP) | VAF 8/224 reads (4%) | called by muse, mutect2
- KIF20B | c.2883C>T p.I961= (on ENST00000371728 / NM_001284259.2; = p.I921= on NM_016195.4) | Silent (SNP) | VAF 72/124 reads (58%) | catalogued as COSV53312824; called by muse, mutect2, varscan2
- KLK12 | c.60G>A p.P20= | Silent (SNP) | VAF 128/347 reads (37%) | catalogued as rs1416224337; called by muse, mutect2, varscan2
- KRT6B | c.1251G>A p.E417= | Silent (SNP) | VAF 173/822 reads (21%) | called by muse, mutect2, varscan2
- KRTAP4-5 | c.231C>A p.R77= | Silent (SNP) | VAF 65/262 reads (25%) | catalogued as rs1270725753; called by muse, mutect2, varscan2
- LYPD1 | c.414G>A p.S138= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs759690239, COSV100257870; called by muse, mutect2
- MAP10 | c.1602A>T p.I534= | Silent (SNP) | VAF 60/226 reads (27%) | called by muse, mutect2, varscan2
- MAP3K15 | c.2139G>A p.L713= | Silent (SNP) | VAF 131/203 reads (65%) | called by muse, mutect2, varscan2
- MROH2A | c.3477C>G p.L1159= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- MTMR3 | c.2730G>A p.L910= | Silent (SNP) | VAF 119/474 reads (25%) | catalogued as rs748216192; called by muse, mutect2, varscan2
- MUC16 | c.1272G>T p.T424= | Silent (SNP) | VAF 75/244 reads (31%) | called by muse, mutect2
- MUC4 | c.3486C>T p.S1162= | Silent (SNP) | VAF 142/1166 reads (12%) | called by muse, varscan2
- MYLK3 | c.231G>A p.G77= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV101189100; called by muse, mutect2, varscan2
- MYPN | c.3532C>T p.L1178= | Silent (SNP) | VAF 26/600 reads (4%) | called by muse, mutect2
- NEB | c.10620T>A p.I3540= | Silent (SNP) | VAF 87/254 reads (34%) | called by muse, mutect2, varscan2
- NFIC | c.1065C>T p.P355= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs746713531; called by muse, mutect2, varscan2
- NFKBIE | c.486G>A p.L162= (on ENST00000275015; = p.L23= on NM_004556.3) | Silent (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1467C>T p.S489= | Silent (SNP) | VAF 216/814 reads (27%) | catalogued as rs775677265; called by muse, varscan2
- NRXN1 | c.855G>A p.T285= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs201753471, COSV58495644; called by muse, mutect2
- OR2C1 | c.297C>T p.T99= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV59240097; called by muse, mutect2, varscan2
- OR2L5 | c.744T>G p.T248= | Silent (SNP) | VAF 75/203 reads (37%) | called by muse, mutect2, varscan2
- OR2Z1 | c.388C>T p.L130= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as rs1555756742; called by muse, mutect2, varscan2
- OTC | c.375G>C p.T125= | Silent (SNP) | VAF 66/118 reads (56%) | catalogued as COSV50003764; called by muse, mutect2, varscan2
- PALM3 | c.1098G>T p.V366= (on ENST00000340790; = p.V381= on NM_001145028.2) | Silent (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- PAPPA | c.729T>C p.S243= | Silent (SNP) | VAF 80/214 reads (37%) | called by muse, mutect2, varscan2
- PATJ | c.2967C>A p.I989= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV57159783; called by muse, mutect2, varscan2
- PAX2 | c.567G>T p.G189= | Silent (SNP) | VAF 391/698 reads (56%) | catalogued as COSV62290632; called by muse, mutect2, varscan2
- PHF2 | c.2481C>T p.A827= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100823245; called by muse, mutect2, varscan2
- PROX1 | c.468C>A p.R156= | Silent (SNP) | VAF 73/330 reads (22%) | called by muse, mutect2, varscan2
- PRX | c.3276G>A p.V1092= | Silent (SNP) | VAF 86/317 reads (27%) | called by muse, mutect2, varscan2
- PSMD8 | c.582C>G p.L194= | Silent (SNP) | VAF 76/303 reads (25%) | catalogued as COSV53058468; called by muse, mutect2, varscan2
- QKI | c.504G>A p.L168= | Silent (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- RBM46 | c.1272A>G p.V424= | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- RELN | c.10014C>T p.S3338= | Silent (SNP) | VAF 115/374 reads (31%) | called by muse, mutect2, varscan2
- RP1 | c.1035G>A p.K345= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- RP1L1 | c.5496C>A p.A1832= | Silent (SNP) | VAF 100/211 reads (47%) | called by muse, mutect2, varscan2
- RUFY1 | c.1890G>A p.V630= | Silent (SNP) | VAF 54/202 reads (27%) | called by muse, mutect2, varscan2
- RYR3 | c.11415G>T p.L3805= (on ENST00000389232; = p.L3806= on NM_001036.6) | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- S1PR1 | c.492C>T p.I164= | Silent (SNP) | VAF 90/292 reads (31%) | called by muse, mutect2, varscan2
- SAMD12 | c.63T>C p.A21= | Silent (SNP) | VAF 51/344 reads (15%) | catalogued as rs1336527964; called by muse, mutect2, varscan2
- SCGB2B2 | c.183C>T p.L61= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as COSV64857201; called by muse, mutect2
- SENP2 | c.993G>A p.L331= | Silent (SNP) | VAF 75/529 reads (14%) | called by muse, mutect2, varscan2
- SERPINE2 | c.681G>T p.R227= | Silent (SNP) | VAF 18/378 reads (5%) | called by muse, mutect2
- SHCBP1 | c.2016C>T p.F672= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs769369400; called by muse, varscan2
- SMC1B | c.1797G>A p.K599= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- SMURF2 | c.450C>T p.D150= | Silent (SNP) | VAF 41/186 reads (22%) | called by muse, mutect2, varscan2
- SVOP | c.387C>G p.V129= | Silent (SNP) | VAF 29/264 reads (11%) | called by muse, mutect2, varscan2
- SYAP1 | c.738C>G p.P246= | Silent (SNP) | VAF 58/207 reads (28%) | called by muse, mutect2, varscan2
- TBC1D16 | c.1143G>C p.L381= | Silent (SNP) | VAF 57/185 reads (31%) | called by muse, mutect2, varscan2
- TDRD1 | c.1638T>C p.D546= | Silent (SNP) | VAF 163/267 reads (61%) | called by muse, mutect2, varscan2
- TLK1 | c.1815C>A p.I605= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- TM4SF5 | c.540G>T p.A180= | Silent (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- TMEM132C | c.3006G>C p.P1002= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as COSV59423367; called by muse, mutect2
- TMEM59 | c.6G>A p.A2= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs1275379173; called by mutect2, varscan2
- TMEM59L | c.18G>T p.L6= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, varscan2
- TMTC4 | c.1162C>T p.L388= (on ENST00000376234 / NM_001350577.2; = p.L407= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV60893357, COSV60893648; called by muse, mutect2, varscan2
- TNFRSF6B | c.63G>C p.L21= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs781580521; called by mutect2, varscan2
- TOPAZ1 | c.4104T>C p.A1368= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TPRN | c.42G>T p.A14= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- TRIM64B | c.375C>T p.H125= | Silent (SNP) | VAF 55/409 reads (13%) | called by muse, mutect2, varscan2
- UNC13C | c.3081T>G p.G1027= | Silent (SNP) | VAF 88/288 reads (31%) | called by muse, varscan2
- WNK1 | c.4806C>G p.P1602= (on ENST00000315939 / NM_018979.4; = p.P1355= on NM_014823.3) | Silent (SNP) | VAF 119/471 reads (25%) | catalogued as COSV60030444; called by muse, mutect2, varscan2
- ZBTB2 | c.1224C>T p.H408= | Silent (SNP) | VAF 85/417 reads (20%) | catalogued as rs370849098; called by muse, mutect2, varscan2
- ZC3H12B | c.1548T>A p.P516= | Silent (SNP) | VAF 121/198 reads (61%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.912C>T p.D304= | Silent (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ZMAT5 | c.75G>A p.L25= | Silent (SNP) | VAF 163/584 reads (28%) | catalogued as rs756582080; called by muse, mutect2, varscan2
- ZNF335 | c.1125G>C p.V375= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- ZNF547 | c.84C>T p.L28= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs746675171, COSV99987995; called by muse, mutect2, varscan2
- ZNF708 | c.1461G>T p.L487= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs189030857; called by muse, mutect2, varscan2
- ZNF804B | c.2700A>G p.L900= | Silent (SNP) | VAF 81/304 reads (27%) | catalogued as rs771678381; called by muse, mutect2, varscan2
- ZNF83 | c.774G>A p.E258= | Silent (SNP) | VAF 24/75 reads (32%) | called by muse, varscan2
- ZNF862 | c.2334C>A p.I778= | Silent (SNP) | VAF 62/225 reads (28%) | catalogued as COSV56223626; called by muse, mutect2, varscan2
- AC008758.3 | n.422C>A | RNA (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- ACACA | c.6042-36A>G | Intron (SNP) | VAF 104/365 reads (28%) | catalogued as rs1158920395; called by muse, mutect2, varscan2
- ADAM15 | c.2424+10G>C | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as rs765471884; called by mutect2, varscan2
- ADAMTS13 | c.987+25G>T | Intron (SNP) | VAF 63/143 reads (44%) | called by muse, mutect2, varscan2
- AF121898.1 | n.205+24524G>T | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- AHSA1 | c.845-244C>T | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs934695543; called by muse, varscan2
- ALDH1A2 | c.902-38A>T | Intron (SNP) | VAF 49/155 reads (32%) | called by muse, mutect2, varscan2
- AOC4P | n.113C>T | RNA (SNP) | VAF 63/236 reads (27%) | called by muse, mutect2, varscan2
- AP000769.1 | n.18G>T | RNA (SNP) | VAF 30/139 reads (22%) | catalogued as rs368587810; called by muse, mutect2, varscan2
- ASTN2 | c.3782+3063A>G | Intron (SNP) | VAF 150/256 reads (59%) | called by muse, mutect2, varscan2
- ATRN | c.3802-8677A>C | Intron (SNP) | VAF 69/164 reads (42%) | catalogued as COSV53528736; called by muse, mutect2, varscan2
- BCAS4 | c.355-1197G>T | Intron (SNP) | VAF 77/291 reads (26%) | called by muse, mutect2, varscan2
- BLK | c.1029+703G>C | Intron (SNP) | VAF 87/173 reads (50%) | catalogued as rs892665250; called by muse, mutect2, varscan2
- BNIP2 | c.-4G>C | 5'UTR (SNP) | VAF 36/167 reads (22%) | catalogued as COSV51105168; called by muse, mutect2, varscan2
- BOLL | c.-1G>T | 5'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- C2CD6 | c.1506+53C>G | Intron (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- C3AR1 | c.*2A>C | 3'UTR (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2
- C5orf17 | n.348G>T | RNA (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- CACTIN | c.*19+15G>C | Intron (SNP) | VAF 40/151 reads (26%) | called by muse, mutect2, varscan2
- CAMK2A | c.944-11C>G | Intron (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- CBLIF | c.370+14G>C | Intron (SNP) | VAF 67/509 reads (13%) | called by muse, mutect2, varscan2
- CCDC127 | c.121+40G>C | Intron (SNP) | VAF 84/283 reads (30%) | called by muse, mutect2, varscan2
- CCDC18 | c.-3+73G>C | Intron (SNP) | VAF 30/116 reads (26%) | catalogued as COSV100159416; called by muse, mutect2, varscan2
- CDC14A | c.1755+31C>G | Intron (SNP) | VAF 58/195 reads (30%) | called by muse, mutect2, varscan2
- CRYM | c.795+30G>A | Intron (SNP) | VAF 61/178 reads (34%) | catalogued as rs1355948086; called by muse, mutect2, varscan2
- DCAF17 | c.*3778G>T | 3'UTR (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- DPF2 | c.637+499T>G | Intron (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- EIF4A2 | c.209-97G>C | Intron (SNP) | VAF 24/303 reads (8%) | called by muse, mutect2
- EIF4G1 | c.425-39G>T | Intron (SNP) | VAF 40/390 reads (10%) | called by muse, mutect2, varscan2
- EML1 | c.1105-30G>A | Intron (SNP) | VAF 154/493 reads (31%) | called by muse, mutect2, varscan2
- FAM205BP | n.114G>T | RNA (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- FBXO30 | chr6:145791445 G>T | 3'Flank (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-1377C>T | Intron (SNP) | VAF 50/155 reads (32%) | called by muse, varscan2
- GABRG2 | c.1249-1368C>G | Intron (SNP) | VAF 37/172 reads (22%) | called by muse, varscan2
- GRHL3 | c.17+31C>G | Intron (SNP) | VAF 137/254 reads (54%) | called by muse, mutect2, varscan2
- GUSBP10 | n.106C>A | RNA (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- HEPACAM | c.*726C>T | 3'UTR (SNP) | VAF 28/122 reads (23%) | catalogued as rs1290744747; called by muse, mutect2, varscan2
- HSP90AA4P | n.1900T>C | RNA (SNP) | VAF 58/161 reads (36%) | called by muse, mutect2, varscan2
- IGDCC4 | c.3180+67C>G | Intron (SNP) | VAF 77/312 reads (25%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2833G>A | Intron (SNP) | VAF 66/330 reads (20%) | called by muse, mutect2, varscan2
- IKZF4 | c.-195A>G | 5'UTR (SNP) | VAF 77/251 reads (31%) | catalogued as rs1460777752; called by muse, mutect2, varscan2
- ITGA9 | c.3010-41C>A | Intron (SNP) | VAF 73/181 reads (40%) | called by muse, mutect2, varscan2
- KIAA0930 | c.65-172C>A | Intron (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1887+53C>A | Intron (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- LINC02649 | n.179G>T | RNA (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- LY6G6E | c.179-39G>T | Intron (SNP) | VAF 113/265 reads (43%) | called by muse, mutect2, varscan2
- MAGED1 | c.1486+18_1486+35del | Intron (DEL) | VAF 20/62 reads (32%) | called by pindel, varscan2
- MAMLD1 | c.*543C>T | 3'UTR (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- MCMDC2 | chr8:66922495 T>C | 3'Flank (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30364740 G>A | 3'Flank (SNP) | VAF 73/157 reads (46%) | called by muse, mutect2, varscan2
- MORF4 | n.422T>G | RNA (SNP) | VAF 101/253 reads (40%) | called by muse, mutect2, varscan2
- MSH2 | c.*1454C>A | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- MSL3P1 | n.1051G>T | RNA (SNP) | VAF 202/455 reads (44%) | called by muse, mutect2, varscan2
- NCKAP5L | c.193-39G>C | Intron (SNP) | VAF 122/354 reads (34%) | called by muse, mutect2, varscan2
- NUP42 | c.609+418G>C | Intron (SNP) | VAF 57/130 reads (44%) | called by muse, varscan2
- PATL2 | c.*44A>T | 3'UTR (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- PC | c.1368+3264G>A | Intron (SNP) | VAF 55/188 reads (29%) | catalogued as rs772375415; called by muse, mutect2, varscan2
- PCMTD1 | c.308-4268C>T | Intron (SNP) | VAF 28/130 reads (22%) | catalogued as rs999894835; called by muse, varscan2
- PDLIM3 | c.162-1679_162-1653del | Intron (DEL) | VAF 36/164 reads (22%) | called by mutect2, pindel
- PLA2G2A | c.41-32C>T | Intron (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- PNLDC1 | c.-124G>C | 5'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as rs1340898213; called by muse, mutect2, varscan2
- PPHLN1 | c.*21G>T | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- PTPRC | c.100+1647C>A | Intron (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- RIC8B | c.742-2310C>A | Intron (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- SDR16C5 | c.836+1566G>C | Intron (SNP) | VAF 60/272 reads (22%) | called by muse, mutect2, varscan2
- SLC16A12 | c.*2473C>A | 3'UTR (SNP) | VAF 43/91 reads (47%) | called by mutect2, varscan2
- SLC16A12 | c.*2472C>A | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*36T>A | 3'UTR (SNP) | VAF 119/341 reads (35%) | called by muse, mutect2, varscan2
- SNORD114-20 | n.54C>G | RNA (SNP) | VAF 45/214 reads (21%) | called by muse, mutect2, varscan2
- SNORD115-40 | n.21A>G | RNA (SNP) | VAF 112/394 reads (28%) | called by muse, mutect2, varscan2
- SOX5 | c.1165-8735T>A | Intron (SNP) | VAF 56/221 reads (25%) | called by muse, mutect2, varscan2
- SPAG11B | c.*95A>T | 3'UTR (SNP) | VAF 103/415 reads (25%) | called by muse, mutect2, varscan2
- SPINT1 | c.-147G>A | 5'UTR (SNP) | VAF 23/82 reads (28%) | catalogued as rs1381265352; called by muse, mutect2, varscan2
- SRP14 | c.243+96C>T | Intron (SNP) | VAF 27/88 reads (31%) | catalogued as rs1243318378; called by muse, mutect2, varscan2
- TAP2 | c.1461+38C>G | Intron (SNP) | VAF 156/371 reads (42%) | called by muse, mutect2, varscan2
- TMEM135 | c.*5700G>T | 3'UTR (SNP) | VAF 73/280 reads (26%) | called by muse, mutect2, varscan2
- TMEM94 | c.955-17G>T | Intron (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.-147+12141C>T | Intron (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- TPM1 | c.115-286G>C | Intron (SNP) | VAF 88/321 reads (27%) | called by muse, mutect2, varscan2
- TPTE2P5 | n.123-4342G>C | Intron (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- TSC22D4 | c.930-125C>T | Intron (SNP) | VAF 17/54 reads (31%) | catalogued as rs1218159851; called by muse, mutect2, varscan2
- TUBA1B | c.4-674C>T | Intron (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- USP32 | c.-19C>T | 5'UTR (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- VIPR2 | c.357+6758_357+6772del | Intron (DEL) | VAF 11/115 reads (10%) | called by mutect2, pindel
- VSX1 | c.628-36T>C | Intron (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
- XIAP | c.*5874A>G | 3'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as rs1179829771; called by muse, mutect2
- ZIC4 | c.-16+871T>C | Intron (SNP) | VAF 132/794 reads (17%) | called by muse, mutect2, varscan2
- ZNF665 | c.-54+10436G>T | Intron (SNP) | VAF 52/149 reads (35%) | catalogued as rs755086697; called by muse, mutect2, varscan2
- ZNF812P | n.1612G>C | RNA (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
